Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J5, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J5-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:

AN -YEAR-OLD CAUCASIAN MALE WITH RIGHT RENAL MASS.

PREOPERATIVE DIAGNOSIS:

NA

SPECIMEN TYPE(S):

A: 11TH RIB, GROSS ONLY
B: RIGHT KIDNEY FS

FINAL DIAGNOSIS:

- A. PORTION OF 11TH RIB, SEGMENTAL RESECTION:
One piece of rib (gross only).
- B. RIGHT KIDNEY, PARTIAL NEPHRECTOMY:
Papillary renal cell carcinoma, type III.
Tumor size: 10.9 cm in maximum dimension.
Renal capsular invasion: Not identified.
Margins of resection: Free of malignancy.
Pathologic stage: T2 NX MX.

*ICD O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS
64.9
JW 4/28/14*

I, M.D., the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:

NA

INTRAOPERATIVE DIAGNOSIS:

FSB. RIGHT KIDNEY:
FSB1. Renal cell carcinoma, mostly necrotic.
Margin free of tumor.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by

I, M.D., have performed the intraoperative consultation and issued the above diagnoses.

GROSS DESCRIPTION:

- A. Specimen A is received fresh labeled "right number 11 rib, portion." The specimen consist of 2 fragments of rib measuring 5.6 x 1.2 x 0.7 cm. The specimen is grossly unremarkable. Gross examination only.

[page 2 of 2]
B. Specimen B is received fresh labeled "right kidney." The specimen consists of an ovoid mass measuring 20.0 x 15.0 x 12.0 cm and weighing 999.3 g. The parenchymal margin of resection is irregular and is inked in black. The perinephric fat margin of resection is inked in blue and is grossly unremarkable. On sectioning the specimen, an ovoid, well defined, tan-yellow, hemorrhagic and partially necrotic tumor is present measuring 13 x 10.5 x 9 cm. The tumor is located at 0.7 cm from closest inked parenchymal margin of resection. The perinephric fat margin of resection is not grossly involved by tumor. There are areas of necrosis (55% of the tumor). Representative fresh tissue is not submitted to the tissue procurement laboratory. Representative sections are submitted as follows:

FSH1: Tumor in relation to closest inked margin of resection (parenchyma).
H1: Perpendicular section perinephric fat margin of resection.
H2-H10: Tumor.

Source: NCI Genomic Data Commons file a7b0b277-0139-4bef-9c39-cf58ec9a8ba3 (TCGA-2Z-A9J5.3A998600-37C3-4597-90D6-F92934879A2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).